Somatic mutation profile of tumor specimen TARGET-10-PARDFB-09A (aliquot TARGET-10-PARDFB-09A-01D) from TARGET case TARGET-10-PARDFB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,138 days).
Specimen TARGET-10-PARDFB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a519235f-fa8a-46e2-a27d-559e9c8cda0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDFB-10A (Blood Derived Normal), aliquot TARGET-10-PARDFB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/584e8503-42ef-44a6-b0da-84b2e6959dd4

The open-access MAF lists 66 somatic variants for this specimen: 15 protein-altering or splice-affecting, 38 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 38, Missense Mutation 10, Intron 7, 5'UTR 5, Splice Region 2, Translation Start Site 1, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FHL1 | c.552T>G p.D184E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61779592; called by muse, mutect2
- MED12 | c.2542-3C>T | Splice Region (SNP) | VAF 4/33 reads (12%) | catalogued as COSV61349284; called by muse, mutect2
- MYOM3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs866678433, COSV58392409; called by muse, mutect2, varscan2
- OLFM3 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100129734; called by muse, mutect2
- WDR90 | c.2400C>G p.F800L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs1371643750, COSV53466047; called by muse, mutect2, varscan2
- AEBP2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- CSE1L | c.1620C>T p.L540= | Splice Region (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- ELOVL6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ETV1 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUCB2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RELN | c.4837T>C p.S1613P | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.246); called by muse, varscan2
- RNF130 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- SLTM | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- TNPO1 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- TRAJ28 | c.1_3delinsTCAGAGACCCC p.Y2Rfs*? | Frame Shift Ins (INS) | VAF 37/79 reads (47%) | called by pindel, varscan2*
- AMBRA1 | c.2085A>G p.E695= (on ENST00000458649 / NM_001367468.1; = p.E605= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as rs1304721302; called by muse, mutect2
- ATP2B1 | c.1965T>C p.F655= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- BCL11A | c.2340C>T p.T780= (on ENST00000335712 / NM_001365609.1; = p.T814= on NM_022893.4) | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- CUX1 | c.1587C>A p.V529= | Silent (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- DGKH | c.3522T>C p.R1174= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- DPP8 | c.2370A>C p.G790= (on ENST00000341861 / NM_001320875.2; = p.G674= on NM_017743.6) | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- DRG1 | c.462T>C p.P154= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- EIF4G3 | c.4551G>A p.S1517= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs775026555; called by mutect2, varscan2
- EML6 | c.654T>C p.G218= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, varscan2
- EMSY | c.3382C>T p.L1128= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV58259525; called by muse, mutect2
- ENOX1 | c.1104C>T p.A368= | Silent (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- FGF13 | c.96A>G p.R32= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- FOXP2 | c.1302T>C p.N434= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1217274628; called by muse, mutect2, varscan2
- GARNL3 | c.9T>G p.V3= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- HEPH | c.396C>T p.Y132= (on ENST00000343002; = p.Y186= on NM_138737.5) | Silent (SNP) | VAF 27/27 reads (100%) | catalogued as rs753905685, COSV100296109; called by muse, mutect2, varscan2
- HOXB7 | c.312C>T p.S104= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- HOXD10 | c.249T>C p.D83= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as rs1299561208, COSV50897994; called by muse, mutect2
- KAT6B | c.1902A>G p.R634= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- KDM1B | c.1380A>G p.K460= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- KDM6A | c.1281T>C p.I427= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- KDM6A | c.2040C>T p.N680= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1215825916, COSV65036827; called by muse, mutect2
- LARGE1 | c.2190C>G p.L730= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- LIMCH1 | c.2436G>A p.E812= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- LSM1 | c.219A>G p.L73= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as rs1563274824, COSV60949061; called by muse, mutect2
- NRG2 | c.1122T>C p.N374= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- OCRL | c.1725A>G p.E575= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- PCDH9 | c.1815A>G p.K605= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- PLCXD3 | c.420G>A p.V140= | Silent (SNP) | VAF 10/187 reads (5%) | catalogued as COSV100125311; called by muse, mutect2
- PLP1 | c.264T>C p.A88= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, varscan2
- PUM1 | c.633A>G p.R211= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV57087031; called by muse, mutect2
- SARS1 | c.510T>C p.H170= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs774036669; called by mutect2, varscan2
- SCAMP3 | c.426T>C p.C142= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SI | c.624C>T p.N208= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs769677927; called by muse, mutect2, varscan2
- TUBA1A | c.816T>C p.Y272= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1256697537; called by muse, varscan2
- VIRMA | c.3435A>G p.K1145= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ZCCHC17 | c.657A>G p.T219= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ZIC3 | c.1380T>C p.P460= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV54972276; called by muse, varscan2
- ZNF148 | c.1818C>A p.S606= | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- AL109984.1 | n.186+1592G>A | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as rs1312057599, COSV63752276; called by muse, mutect2
- BCORL1 | c.-20T>G | 5'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, varscan2
- CIAO3 | c.67-199C>T | Intron (SNP) | VAF 39/102 reads (38%) | catalogued as rs1489665266; called by muse, mutect2, varscan2
- CLK3 | c.814-122C>T | Intron (SNP) | VAF 17/241 reads (7%) | catalogued as COSV61414633; called by muse, mutect2
- HOXC9 | c.-7C>T | 5'UTR (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- LINC00173 | n.633T>C | RNA (SNP) | VAF 6/99 reads (6%) | catalogued as rs982460112; called by muse, mutect2
- NFIB | c.-26C>G | 5'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- NFIB | c.-115C>T | 5'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- PON2 | c.201+66G>A | Intron (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-54T>A | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SCG5 | c.377-29G>A | Intron (SNP) | VAF 32/62 reads (52%) | catalogued as rs780445112; called by muse, mutect2, varscan2
- SETD5 | c.177+127A>C | Intron (SNP) | VAF 8/96 reads (8%) | catalogued as COSV56707241; called by muse, mutect2
- YAF2 | c.152+1713T>C | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
